Somatic mutation profile of tumor specimen TCGA-85-A510-01A (aliquot TCGA-85-A510-01A-11D-A26M-08) from TCGA case TCGA-85-A510, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.1 years (27,067 days).
Specimen TCGA-85-A510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95d61913-286c-4375-9c1e-29673c0becc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A510-10A (Blood Derived Normal), aliquot TCGA-85-A510-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee7f8f14-9493-4ad9-88f2-4e6b158783d9

The open-access MAF lists 171 somatic variants for this specimen: 122 protein-altering or splice-affecting, 41 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 41, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 4, RNA 3, Intron 3, Frame Shift Ins 2, Nonstop Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 22/40 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99521506; called by muse, mutect2, varscan2
- AGBL2 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | catalogued as COSV100101316, COSV100102184; called by muse, mutect2, varscan2
- ARHGAP11A | c.2993G>T p.R998M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100276674; called by muse, mutect2, varscan2
- ARRDC4 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164315; called by muse, mutect2, varscan2
- ASPH | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199833011; called by muse, mutect2, varscan2
- ATE1 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816771; called by muse, mutect2
- AXDND1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs754805292, COSV100858256, COSV62650481; called by mutect2, varscan2
- BARX1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99560935; called by muse, mutect2
- BCR | c.1492A>T p.M498L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100006027; called by muse, mutect2, varscan2
- C18orf54 | c.1047-1G>T p.X349_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100266341; called by mutect2, varscan2
- C6 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666561; called by muse, mutect2, varscan2
- C6 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99666563; called by muse, mutect2, varscan2
- CCDC120 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376435528, COSV100900573; called by muse, mutect2, varscan2
- CCDC93 | c.81G>C p.L27F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.705); catalogued as COSV100098412; called by muse, mutect2, varscan2
- CD22 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99322898; called by muse, mutect2, varscan2
- CD8B | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100514379; called by muse, varscan2
- CHST12 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.198); catalogued as COSV99324317; called by muse, mutect2, varscan2
- CNTN6 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs371266935; called by muse, mutect2, varscan2
- COL13A1 | c.1625G>T p.G542V (on ENST00000398978 / NM_001130103.2; = p.G485V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637300; called by muse, mutect2
- CPD | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99852496; called by muse, mutect2, varscan2
- CPXCR1 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99341987; called by muse, mutect2, varscan2
- DDX58 | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101152519; called by muse, mutect2, varscan2
- DGKG | c.627T>G p.H209Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99402535; called by muse, mutect2, varscan2
- DHX33 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs368918561; called by muse, mutect2, varscan2
- DNAH3 | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99765188; called by muse, mutect2, varscan2
- DOCK2 | c.3585G>T p.E1195D | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56945743, COSV99910491; called by muse, mutect2, varscan2
- ELK1 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV99901883; called by muse, mutect2, varscan2
- ELOA2 | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99795996; called by muse, mutect2, varscan2
- FMO3 | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV100882401; called by muse, mutect2, varscan2
- FOXL2 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as CD084129, COSV100374356; called by muse, varscan2
- GLG1 | c.468T>G p.N156K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.764); catalogued as COSV99215325; called by muse, mutect2, varscan2
- GRIP1 | c.2938A>T p.K980* (on ENST00000359742 / NM_001379345.1; = p.K928* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | catalogued as COSV99668204; called by muse, mutect2, varscan2
- GRM1 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs899128781, COSV51237481; called by muse, mutect2, varscan2
- GRM7 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100735812; called by muse, mutect2, varscan2
- HECTD1 | c.2245G>T p.G749* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV101237305; called by muse, mutect2, varscan2
- HIBADH | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99606921; called by muse, mutect2, varscan2
- HSD3B2 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as rs761068679, COSV101027423; called by muse, mutect2, varscan2
- HTRA2 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99239476; called by muse, mutect2
- HUWE1 | c.12032G>T p.G4011V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53350215, COSV99470789; called by muse, mutect2
- IRX6 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51859727, COSV99306213; called by muse, mutect2, varscan2
- JPH2 | c.1937C>A p.T646N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100881608; called by muse, mutect2, varscan2
- KCNH8 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.062); catalogued as COSV100108643, COSV60455533; called by muse, mutect2, varscan2
- KIAA0319 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401911854, COSV100985234; called by muse, mutect2, varscan2
- KIF18B | c.1486G>A p.A496T (on ENST00000593135 / NM_001265577.2; = p.A508T on NM_001264573.2) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as COSV100191805, COSV59276976; called by muse, mutect2, varscan2
- KLRF1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.06); catalogued as COSV99684300; called by muse, mutect2, varscan2
- KRT38 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as COSV99878099; called by muse, mutect2, varscan2
- KRTAP13-4 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV100481713; called by muse, mutect2, varscan2
- LCA5 | c.1411C>A p.L471M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.303); catalogued as COSV100878176; called by muse, mutect2, varscan2
- LPP | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV100446340; called by muse, mutect2, varscan2
- LRRIQ1 | c.1608del p.E537Kfs*5 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs747679413; called by mutect2, pindel, varscan2
- MARCHF4 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99814093, COSV99814773; called by muse, mutect2, varscan2
- MBD1 | c.1520A>T p.D507V (on ENST00000269468 / NM_001323950.1; = p.D451V on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV99495561; called by muse, mutect2, varscan2
- MUC5AC | c.15127G>A p.G5043S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs754161223, COSV100611320; called by muse, mutect2, varscan2
- MUC7 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs775270784, COSV100512197; called by muse, mutect2, varscan2
- MYO1B | c.1579G>T p.V527F | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100268685, COSV58436768; called by muse, mutect2, varscan2
- MYPN | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV100589593; called by muse, mutect2, varscan2
- NAV3 | c.4441G>T p.V1481L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV57101301; called by muse, mutect2, varscan2
- NCOA3 | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100507197; called by muse, mutect2, varscan2
- NIBAN3 | c.1468T>G p.C490G | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV99961821; called by muse, mutect2, varscan2
- NMRK1 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100737897; called by muse, varscan2
- NOTCH2 | c.3295G>T p.D1099Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99862887; called by muse, mutect2
- NOTCH2 | c.3293G>T p.C1098F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56685381, COSV99862889; called by muse, mutect2
- NUP155 | c.804G>T p.L268F (on ENST00000231498 / NM_153485.3; = p.L209F on NM_004298.4) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV99192260; called by muse, mutect2, varscan2
- NYX | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100699373; called by muse, varscan2
- OR2L13 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813681; called by muse, mutect2, varscan2
- OR52E2 | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV100384642; called by muse, mutect2, varscan2
- OR52W1 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100258587; called by muse, mutect2, varscan2
- PAGE5 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.516); catalogued as COSV99215696; called by muse, mutect2, varscan2
- PAX5 | c.178G>T p.V60F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100814062, COSV63914770; called by muse, varscan2
- PCDHB3 | c.1315G>T p.V439L | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as COSV99164206; called by muse, mutect2, varscan2
- PCDHGB2 | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99531619; called by muse, mutect2, varscan2
- PCSK1 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100226849, COSV60736111; called by muse, mutect2, varscan2
- PDGFRA | c.2822C>A p.P941H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955556; called by muse, mutect2, varscan2
- PDS5B | c.3372+2T>A p.X1124_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100220533; called by muse, mutect2, varscan2
- PHKA2 | c.2389G>T p.G797* | Nonsense Mutation (SNP) | VAF 46/222 reads (21%) | catalogued as COSV101176711; called by muse, mutect2, varscan2
- PLXNC1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.263); catalogued as COSV99312507, COSV99312535, COSV99313564; called by muse, mutect2, varscan2
- POU2F1 | c.463G>A p.A155T (on ENST00000541643 / NM_001365848.1; = p.A178T on NM_002697.4) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs376733697; called by muse, mutect2, varscan2
- PTPRT | c.1982T>A p.L661Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100625481; called by muse, mutect2, varscan2
- PXDNL | c.2026G>T p.V676L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV100681618; called by muse, mutect2, varscan2
- RASAL2 | c.1883G>C p.R628P | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.762); catalogued as COSV100862420; called by muse, mutect2, varscan2
- RB1 | c.306T>A p.C102* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99923318; called by muse, mutect2, varscan2
- RBFOX1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs369122393, COSV60943474; called by muse, mutect2, varscan2
- RETN | c.153C>G p.C51W | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55569207, COSV99679354; called by muse, mutect2, varscan2
- RP1 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99606391; called by muse, mutect2, varscan2
- RXRG | c.1390T>A p.*464Rext*39 | Nonstop Mutation (SNP) | VAF 73/135 reads (54%) | catalogued as COSV100717251; called by muse, mutect2, varscan2
- RYR2 | c.14122T>A p.W4708R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100768243; called by muse, mutect2, varscan2
- SCN5A | c.3250G>T p.G1084C (on ENST00000333535 / NM_198056.3; = p.G1083C on NM_000335.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.38); catalogued as CM085685, COSV100346703, COSV100351049; called by muse, mutect2, varscan2
- SDR9C7 | c.302-1G>T p.X101_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99524508; called by muse, mutect2, varscan2
- SLC12A1 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100372208; called by muse, mutect2
- SLC19A1 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs770678515, COSV100229129; called by muse, mutect2, varscan2
- SLC39A12 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV101069857; called by muse, mutect2, varscan2
- SPATA46 | c.645C>A p.Y215* | Nonsense Mutation (SNP) | VAF 113/207 reads (55%) | catalogued as COSV100722854; called by muse, mutect2, varscan2
- SYNE1 | c.19790A>G p.D6597G (on ENST00000367255 / NM_182961.4; = p.D6526G on NM_033071.3) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV99554697; called by muse, mutect2, varscan2
- TAAR6 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99256483, COSV99256665; called by muse, mutect2, varscan2
- TGM2 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100821497; called by muse, mutect2, varscan2
- THSD7B | c.2746G>T p.V916L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV99744997, COSV99749291; called by muse, mutect2, varscan2
- TNNT2 | c.827A>G p.N276S (on ENST00000236918; = p.N273S on NM_000364.4) | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs990771026; called by muse, mutect2
- TRAK1 | c.484T>C p.S162P (on ENST00000327628 / NM_001349247.2; = p.S104P on NM_014965.5) | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100409768; called by muse, mutect2, varscan2
- TRIM6 | c.875-1G>C p.X292_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99546200; called by muse, mutect2, varscan2
- TTN | c.80233C>A p.L26745M (on ENST00000591111; = p.L19321M on NM_003319.4) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | PolyPhen possibly damaging (0.487); catalogued as COSV100596183; called by muse, mutect2, varscan2
- TTN | c.38796G>T p.M12932I (on ENST00000591111; = p.M5508I on NM_003319.4) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | PolyPhen benign (0); catalogued as COSV100596190, COSV100605828; called by muse, mutect2, varscan2
- VWA5A | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100795544; called by muse, mutect2, varscan2
- WAPL | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as COSV100076511, COSV53940520; called by muse, mutect2, varscan2
- XYLT1 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377021125; called by muse, mutect2, varscan2
- ZBED2 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV51920043, COSV99342403; called by muse, mutect2, varscan2
- ZHX2 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100072616; called by muse, mutect2, varscan2
- ZMYM6 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV100451540; called by muse, mutect2, varscan2
- ZNF23 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV100612072; called by muse, mutect2, varscan2
- ZNF474 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99682020, COSV99682283; called by muse, mutect2, varscan2
- ZNF675 | c.1616A>T p.E539V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100704914; called by muse, mutect2, varscan2
- ZSCAN1 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs1031389692, COSV99991373; called by muse, mutect2, varscan2
- ZYX | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs765958504, COSV59555702; called by muse, varscan2
- ATP6V1C1 | c.239_246del p.L80* | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- DNAH7 | c.6864del p.D2288Efs*7 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | called by mutect2, pindel, varscan2
- FCGBP | c.5474A>T p.D1825V | Missense Mutation (SNP) | VAF 55/2026 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCGBP | c.5356G>A p.D1786N | Missense Mutation (SNP) | VAF 43/1520 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.337); called by muse, mutect2
- FOXD4L4 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); called by mutect2, varscan2
- FZD3 | c.244del p.C82Vfs*62 | Frame Shift Del (DEL) | VAF 61/228 reads (27%) | called by mutect2, pindel, varscan2
- IGKV1-27 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLEKHO1 | c.364dup p.S122Ffs*20 | Frame Shift Ins (INS) | VAF 38/110 reads (35%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.1963dup p.R655Kfs*21 | Frame Shift Ins (INS) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- ASPHD1 | c.105G>A p.Q35= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs747388392, COSV100435128, COSV58102056; called by muse, mutect2, varscan2
- BCR | c.1491G>A p.E497= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100006025; called by muse, mutect2, varscan2
- CACNA1C | c.2053C>A p.R685= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV59768803; called by muse, mutect2
- CD22 | c.114C>G p.A38= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV50049528, COSV99322899; called by muse, mutect2, varscan2
- CFAP47 | c.2418C>A p.S806= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99934441; called by muse, mutect2, varscan2
- CIAO1 | c.360G>T p.L120= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99302484; called by muse, mutect2, varscan2
- CLYBL | c.399G>T p.L133= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100184659; called by muse, mutect2, varscan2
- CRACR2A | c.957G>T p.L319= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99364648; called by muse, mutect2, varscan2
- DARS1 | c.1278G>A p.L426= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV99927335; called by muse, mutect2, varscan2
- DGKH | c.3078C>T p.A1026= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99818381; called by muse, mutect2, varscan2
- DMC1 | c.729G>A p.Q243= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99319177; called by muse, mutect2, varscan2
- EDRF1 | c.2718G>C p.T906= (on ENST00000356792 / NM_001202438.2; = p.T872= on NM_015608.2) | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100523256, COSV61762892; called by muse, mutect2, varscan2
- FAM234A | c.1008G>A p.G336= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV56999662; called by muse, varscan2
- FCGBP | c.10962C>T p.R3654= | Silent (SNP) | VAF 19/492 reads (4%) | called by muse, mutect2
- FGF4 | c.585C>G p.P195= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV51451099, COSV99395255; called by muse, mutect2, varscan2
- HNF4A | c.177G>A p.L59= | Silent (SNP) | VAF 78/227 reads (34%) | catalogued as COSV100291096, COSV57384972, COSV57387506; called by muse, mutect2, varscan2
- ITGAM | c.1116T>C p.Y372= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs761018913, COSV99791838; called by muse, mutect2, varscan2
- MAP3K14 | c.2709C>T p.T903= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100077366; called by muse, mutect2
- MYH4 | c.2629C>T p.L877= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV99700412; called by muse, mutect2, varscan2
- NPY5R | c.693T>C p.H231= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs759617850, COSV100642654; called by muse, mutect2, varscan2
- NUP214 | c.4674T>A p.T1558= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100845149; called by muse, mutect2, varscan2
- OR11H4 | c.42A>G p.S14= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100197401; called by muse, mutect2, varscan2
- OR4F15 | c.30A>T p.S10= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV100173830; called by muse, mutect2, varscan2
- OR5K1 | c.138G>C p.V46= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV100220878; called by muse, mutect2, varscan2
- OR5T2 | c.741G>T p.L247= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV100506818; called by muse, mutect2, varscan2
- PIDD1 | c.135G>C p.G45= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs982081852, COSV61706719; called by muse, mutect2, varscan2
- PMP2 | c.117C>A p.P39= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99808111; called by muse, mutect2, varscan2
- POLE | c.4503G>T p.G1501= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100265489; called by muse, mutect2, varscan2
- PRDM16 | c.1602G>A p.L534= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as COSV99575601; called by muse, mutect2, varscan2
- PRKACG | c.462C>A p.A154= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV55240598; called by muse, mutect2, varscan2
- PTPRM | c.96G>T p.P32= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100155126, COSV100155210; called by muse, mutect2, varscan2
- REM2 | c.678C>A p.L226= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs909386223, COSV99944556; called by muse, mutect2, varscan2
- SIM2 | c.27C>A p.A9= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99292902; called by muse, mutect2, varscan2
- SLC52A3 | c.1374G>A p.S458= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs758484328, COSV54078997; called by muse, mutect2
- SYNE2 | c.15432G>T p.L5144= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as COSV100646788; called by muse, mutect2, varscan2
- TLR4 | c.1330C>T p.L444= (on ENST00000355622 / NM_138554.5; = p.L404= on NM_003266.4) | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV62922487, COSV62923820; called by muse, mutect2, varscan2
- TRBV27 | c.93C>A p.I31= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- TRGV3 | c.333T>C p.Y111= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.80232T>A p.P26744= (on ENST00000591111; = p.P19320= on NM_003319.4) | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100596187; called by muse, mutect2, varscan2
- TTN | c.10152C>A p.I3384= (on ENST00000591111; = p.I3338= on NM_003319.4) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100596191; called by muse, mutect2, varscan2
- ZBTB41 | c.2301A>T p.P767= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100962865; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156981 C>G | 3'Flank (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2
- AP000769.3 | chr11:65502215 T>G | 5'Flank (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- CACNA1C | c.1391-2491G>A | Intron (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100215764; called by muse, mutect2, varscan2
- CCNQP1 | n.528G>T | RNA (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- MDS2 | n.296C>A | RNA (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2
- PIK3C2B | c.934-1528C>T | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as rs755714640; called by muse, mutect2, varscan2
- SLC39A14 | c.457+1470A>T | Intron (SNP) | VAF 20/141 reads (14%) | catalogued as COSV99249586; called by muse, mutect2, varscan2
- SSPOP | n.7306C>G | RNA (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100022159; called by muse, mutect2, varscan2
